Somatic mutation profile of tumor specimen TCGA-IW-A3M4-01A (aliquot TCGA-IW-A3M4-01A-11D-A21Q-09) from TCGA case TCGA-IW-A3M4, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 48.5 years (17,721 days).
Specimen TCGA-IW-A3M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bac9e77-5bed-47d5-84e2-284f9ac7ec3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IW-A3M4-10B (Blood Derived Normal), aliquot TCGA-IW-A3M4-10B-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e090ec2-97b1-4d69-9a9e-8f04572482a0

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD17 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100429134; called by mutect2, varscan2
- IRS4 | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV64535677; called by muse, mutect2, varscan2
- KANSL1 | c.1652+1G>T p.X551_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as CS124331, COSV52267422, COSV52272538; called by muse, mutect2, varscan2
- KMT2C | c.2979C>A p.I993= | Splice Region (SNP) | VAF 56/147 reads (38%) | catalogued as COSV100071354; called by muse, mutect2, varscan2
- MUC17 | c.12353C>A p.T4118K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as rs200507888; called by muse, mutect2, varscan2
- SLC24A4 | c.1851G>T p.M617I | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV100105640; called by muse, mutect2, varscan2
- ZNF514 | c.755G>C p.R252T | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54633711; called by muse, mutect2, varscan2
- CYP2C19 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ELOA | c.1163_1164insG p.E389Rfs*5 | Frame Shift Ins (INS) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- FBXO48 | c.449A>T p.E150V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2
- FRY | c.5399C>A p.T1800K | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- LYST | c.4745C>A p.S1582* | Nonsense Mutation (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- MORC3 | c.206_216del p.G69Dfs*3 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel, varscan2
- OR7E24 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | called by muse, varscan2
- PATZ1 | c.874C>A p.L292I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- PTPRT | c.1796del p.P599Hfs*2 | Frame Shift Del (DEL) | VAF 40/99 reads (40%) | called by mutect2, pindel, varscan2
- SPINK13 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- USP13 | c.2467C>T p.H823Y | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13A | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- EPHA10 | c.2088C>A p.L696= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- KRT80 | c.1134C>A p.I378= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as COSV57548699; called by muse, mutect2
- LCP2 | c.1020C>T p.N340= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs373164419; called by muse, mutect2, varscan2
- MAP4K4 | c.3138A>G p.E1046= (on ENST00000347699 / NM_001242559.2; = p.E964= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- OPLAH | c.1684C>T p.L562= | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
